Surgical pathology report (de-identified scan), TCGA case TCGA-86-8671, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8671-01A (Primary Tumor).

[page 1 of 3]
[Redacted]

[Redacted]		Microscopic Description	Diagnosis Details
[Redacted]	[Redacted]	???? ?????? ???-???????? ? ???? ?????????? ?????????? ????? ? ??? ? ????????????? ? ???? ??????-???? ? ?????????? ? ? ????????? ?????????.	????????? ??? ? ????????? ?????????? ?, ?????????? ?????????? ?? ????????? ? ? ?? ??????????, ??? ????????? ????, ??? ????? ?????? ?????? ???? ?????????.

[page 2 of 3]
Comments	Formatted Path Report
	LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 4 x 3 x 6 cm Histologic type: Papillary adenocarcinoma Histologic grade: Well differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 3/8 positive for metastasis (Hilar 3/8) Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified

ica ID

[page 3 of 3]
Excision date

--

Source: NCI Genomic Data Commons file 11b39a0d-256b-4e9a-a927-d4ddc2c3527e (TCGA-86-8671.94C08FB3-35A3-494E-90EE-B8DF1D8CF34F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).